Somatic mutation profile of tumor specimen MP2PRT-PANWGG-TMP1-A (aliquot MP2PRT-PANWGG-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANWGG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,335 days).
Specimen MP2PRT-PANWGG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e66e5c5b-4c46-4ecc-adf6-f05570a98001.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWGG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWGG-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a869a231-31bf-4ce9-9292-04476938d933

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 24/367 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- ARHGEF11 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs755424336; called by muse, mutect2, varscan2
- CFP | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 187/690 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV55949887; called by muse, mutect2, varscan2
- KCNC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs552970887; called by muse, mutect2, varscan2
- KDR | c.2865C>G p.I955M | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs1239038856, COSV99816637; called by muse, mutect2, varscan2
- NDC80 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV55248144; called by muse, mutect2, varscan2
- SLC1A7 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as rs139150532; called by muse, mutect2, varscan2
- SLC6A5 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 166/618 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs759574943; called by muse, mutect2
- BCORL1 | c.4238C>G p.S1413* | Nonsense Mutation (SNP) | VAF 24/522 reads (5%) | called by muse, mutect2
- CDKL5 | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSPP1 | c.1039G>C p.D347H (on ENST00000676605; = p.D306H on NM_024790.6) | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAGI1 | c.4266C>A p.D1422E | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); called by muse, mutect2
- MORC4 | c.1735C>T p.L579F | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- RFX3 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 98/274 reads (36%) | called by muse, mutect2, varscan2
- IRX6 | c.27G>A p.P9= | Silent (SNP) | VAF 38/463 reads (8%) | called by muse, mutect2
- ITGB7 | c.714C>T p.D238= | Silent (SNP) | VAF 152/509 reads (30%) | catalogued as rs1415198191, COSV57238891; called by muse, mutect2, varscan2
- RECQL4 | c.3210G>A p.L1070= | Silent (SNP) | VAF 54/473 reads (11%) | catalogued as rs539631209, COSV100020231; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELL | c.474C>T p.D158= (on ENST00000650983; = p.D145= on NM_000655.5) | Silent (SNP) | VAF 52/219 reads (24%) | catalogued as rs1022614911, COSV52550007; called by muse, mutect2, varscan2
- TTC38 | c.1122C>T p.D374= | Silent (SNP) | VAF 158/527 reads (30%) | catalogued as rs1229431909; called by muse, mutect2
